Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5882, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5882-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

1305882

Clinical Diagnosis & History:

Incidental finding of 9cm right renal mass with renal vein thrombus into IVC.

Specimens Submitted:

- 1: SP: Kidney, right with inferior vena cava thrombus, radical nephrectomy
- 2: SP: Adrenal gland right and super hilar lymph nodes, resection
- 3: SP: Lymph nodes, pericaval and paracaval, resection
- 4: SP: Lymph nodes, precaval, resection

DIAGNOSIS:

1. SP: Kidney, right with inferior vena cava thrombus, radical nephrectomy

Tumor Type:

Renal cell carcinoma - Unclassified type
with clear cell and papillary features. See note.

Tumor Size:

Greatest diameter is 9 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis

Renal Vein Invasion

Identified

Gross renal vein thrombus is identified

Surgical Margins:

Tumor cells are noted in the section of renal vein margin. However, per [redacted] the observed renal vein margin were clear.

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Free of tumor

Number of metastatic nodes:0

Number of nodes examined:3

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

[page 2 of 4]
NOTE: The tumor demonstrates combination of papillary and clear cell features. Foci of lympho-vascular invasion are seen. The malignant cells show positive immunoreactivity for CAM 5.2 (patchy), CD10, CA IX (patchy, weak), Rasemase (granular, patchy) while being negative for AE1/AE3, HMB-45, CK7, RCC, 34BE12 and TFE3. The immunoprofile and morphological features most compatible with unclassified type of renal cell carcinoma.

2. Right adrenal gland and super hilar lymph nodes, excision:
- Benign adrenal gland and benign fibro-adipose tissue. No lymphoid tissue identified.

3. SP: Lymph nodes, pericaval and paracaval, resection:

Lymph Nodes:

Not involved

Number of nodes examined: 11

Number of metastatic nodes: 0

4. SP: Lymph nodes, precaval, resection

Lymph Nodes:

Not involved

Number of nodes examined: 7

Number of metastatic nodes: 0

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CK7	
	CA-1X.	
	RCC	
	NEGATIVE	
	CD10	
	34BE12	
	RACEMASE	
	RECUT	
	NEG CONT	
	IMM RECUT	
	AE1:AE3	
	CAM 5.2	
	HMB45-RED.	
	H&E(US)	

Gross Description:

1). The specimen is received fresh for TPS labeled "right kidney with inferior vena cava thrombus" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 919 g in total. The kidney measures 13.5 x 7.0 x 6.0 cm. The attached ureter measures 4.5 cm in length and 0.2 cm in diameter. The attached renal vein measures 1.5 cm in length and 1.0 cm in diameter and is grossly involved by tumor thrombus at the margin. The ureter margin is grossly unremarkable. An adrenal

[page 3 of 4]
[REDACTED]

gland is not identified. The kidney is inked black and bivalved to reveal a light tan soft fairly well-circumscribed tumor mass measuring 9.0 x 6.5 x 5.5 cm. It has focal areas of necrosis, hemorrhage and cystic degeneration. Multiple satellite nodules are also identified. The tumor abuts the capsule and grossly involves the sinus and hilar fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 0.7 cm and the calyces appear normal. One lymph node is identified and submitted. Representative sections are submitted for TPS and for permanent sections. The specimen is photographed.

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

THF-- tumor with hilar fat

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

KC-tumor and capsule

LN-lymph node

[REDACTED]

2). The specimen is received in formalin labeled "Right adrenal gland and super hilar lymph nodes" and consists of a 7.5 x 3.0 x 2.8 cm adrenal gland with abundant attached adipose tissue, with a trimmed weight of 7.9 g. The specimen is serially sectioned to reveal an unremarkable yellow red cortical medullary cut surface with 0.5 x 0.3 cm red-brown hemorrhagic focus involving the cortex. Within the fat there are multiple pink-yellow lymph nodes averaging 0.4 cm which are submitted in their entirety, additional possible lymphoid tissue is entirely submitted. Representative sections are submitted.

Summary of sections:

A- Adrenal

LN -lymph nodes

LT- lymphoid tissue

[REDACTED]

3) The specimen is received in formalin, labeled "pericaval and paracaval lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 0.7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

Add- Additional sections of lymph nodes.

[REDACTED]

4). The specimen is received in formalin, labeled "precaval lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 1.1 cm in greatest dimension. The largest lymph node is bisected and all identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

BLN-- bisected lymph node

Summary of Sections:

Part 1: SP: Kidney, right with inferior vena cava thrombus, radical nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	k	1
2	kc	3
1	ln	1
2	rp	2
3	t	3
2	thf	2

[page 4 of 4]
1	tk	1
2	tsf	2
2	uvm	2

Part 2: SP: Adrenal gland right and super hilar lymph nodes, resection

Block	Sect. Site	PCs
3	A	3
1	LN	1
1	LT	1

Part 3: SP:Lymph nodes, pericaval and paracaval , resection

Block	Sect. Site	PCs
3	add	3
1	LN	1

Part 4: SP: Lymph nodes, precaval, resection

Block	Sect. Site	PCs
1	BLN	1
1	LN	1

Source: NCI Genomic Data Commons file c711af95-1f27-459a-a3dc-e92e37490f0d (TCGA-BQ-5882.835245BA-45BB-4E2C-B1B0-F66736899E00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).